Somatic mutation profile of tumor specimen MP2PRT-PAVMFV-TMP1-A (aliquot MP2PRT-PAVMFV-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVMFV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,170 days).
Specimen MP2PRT-PAVMFV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c53268d3-f105-4ebf-8780-bab556ba4b89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVMFV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVMFV-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e097cba1-1d2d-4e24-a2ab-1beeec2c0048

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, Splice Site 1, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC74A | c.893C>G p.S298C | Missense Mutation (SNP) | VAF 121/385 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs545840828; called by muse, varscan2
- IFIT5 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 55/398 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs150755193; called by muse, mutect2
- TRIM36 | c.298+1G>T p.X100_splice | Splice Site (SNP) | VAF 65/161 reads (40%) | catalogued as COSV56692010; called by muse, mutect2, varscan2
- AKR7L | c.221T>G p.I74S | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- MCM3 | c.1835G>A p.S612N (on ENST00000229854 / NM_001366374.2; = p.S602N on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MXD3 | c.271dup p.A91Gfs*72 | Frame Shift Ins (INS) | VAF 165/485 reads (34%) | called by pindel, varscan2
- PCMTD2 | c.167G>A p.W56* | Nonsense Mutation (SNP) | VAF 196/397 reads (49%) | called by muse, mutect2, varscan2
- YAP1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GSTM2 | c.657G>A p.*219= | Silent (SNP) | VAF 153/347 reads (44%) | catalogued as rs570997796; called by muse, mutect2, varscan2
- PPP1R9A | c.2757+799A>G | Intron (SNP) | VAF 65/132 reads (49%) | called by muse, mutect2, varscan2
